Surgical pathology report (de-identified scan), TCGA case TCGA-24-2027, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-2027-01A (Primary Tumor).

[page 1 of 8]
Name: [REDACTED]
Address: [REDACTED]

Surg. Path. No.:

DOB: [REDACTED]

Sex/Race: [REDACTED]

Location: [REDACTED]

Hosp. No.:

Taken/Received: [REDACTED]

MR No.: [REDACTED]
Service: [REDACTED]
Surgeon: [REDACTED]

TCGA-24-2027

DIAGNOSIS

OVARY, LEFT, SALPINGO-OOPHORECTOMY:

- POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA
- SEROSAL INVOLVEMENT PRESENT

OVARY, RIGHT, SALPINGO-OOPHORECTOMY:

- POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA
- SEROSAL INVOLVEMENT PRESENT

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY:

- METASTATIC SEROUS ADENOCARCINOMA
- HYDROSALPINX

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY:

- NO EVIDENCE OF MALIGNANCY

UTERUS, HYSTERECTOMY:

- SEROSAL INVOLVEMENT BY SEROUS ADENOCARCINOMA
- PROLIFERATIVE PHASE ENDOMETRIUM
- FOCAL ADENOMYOSIS

SOFT TISSUE, OMENTUM, EXCISION:

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA
- LARGEST METASTATIC FOCUS MEASURES 1.0 CM

LYMPH NODES, RIGHT EXTERNAL ILIAC, EXCISION:

- METASTATIC SEROUS ADENOCARCINOMA (11/12 NODES)
- EXTRACAPSULAR EXTENSION BY TUMOR PRESENT

LYMPH NODES, PARA-AORTIC, EXCISION:

- METASTATIC SEROUS ADENOCARCINOMA (7/8 NODES)

LYMPH NODES, LEFT EXTERNAL ILIAC, EXCISION:

- NO EVIDENCE OF MALIGNANCY (0/7 NODES)

[page 3 of 8]
[REDACTED]
[REDACTED]
[REDACTED] Surg. Path. No.:
Name:

SPECIMEN(S) SUBMITTED

Part 1: FS1- OVARY, LEFT, EXCISION
Part 2: X1- OVARY, LEFT, EXCISION
Part 3: RIGHT OVARY
Part 4: UTERUS CERVIX
Part 5: RIGHT EXTERNAL ILIAC LYMPH NODE
Part 6: PARAORTIC LYMPH NODE
Part 7: LEFT EXTERNAL ILIAC LYMPH NODE
Part 8: OMENTUM

HISTORY

The patient is a [REDACTED] who presents with increasing abdominal [REDACTED]. Ultrasound showed a 12 x 6 x 6 cm. mass. Operative procedure: TAH/BSO, lymph node dissection, omentectomy, ascites evacuation. Clinical diagnosis: Stage III-C ovarian carcinoma.

An intraoperative non-microscopic consultation was obtained and interpreted as: "Ovary, left - multiple fragments of polypoid tissue, the largest measuring 14 x 9 x 6 cm. and bearing a recognizable serosal surface between polypoid projections of variable size." [REDACTED]

FROZEN

FS: Ovary, left, excision - "Serous carcinoma." by [REDACTED]

GROSS

The specimens are received in eight containers of formalin, each labelled with the patient's name. The first container is additionally labelled "FS1 - left ovary" and consists of a flat irregular fragment of soft, tan-white tissue measuring 1.8 x 1.2 x 0.3 cm., and represents the remnant of the frozen section. Labelled FS. [REDACTED]

The second container is labelled "X - left ovary" and consists of numerous polypoid fragments of light tan tissue, several which appear to be partially invested by a thin translucent serosa, ranging in size from 1.0 cm. in greatest dimension up to 9.0 x 6.0 x 6.0 cm. The largest fragment shows obvious serosal involvement by nodular, focally papillary excrescences. An area that may represent a portion of distended fallopian tube is identified, covered by papillary excrescences and numerous firm, tan-white

[page 4 of 8]
Name: [REDACTED]

GROSS (continued)

adherent nodules. The fimbriae are not identified grossly. Serial sectioning through this region demonstrates a cystically dilated lumen, and a focal bright yellow focus that may represent a corpus luteum. Representative sections of the nodular masses labelled XA through XF, and sections through the distended fallopian tube segment and adjacent tissue labelled XG and XH. [REDACTED]

The third container is labelled "right ovary" and consists of numerous polypoid tissue fragments, some partially invested by serosa, ranging from 1.0 cm. in greatest dimension up to 9.0 x 7.5 x 5.5 cm. In areas where there is recognizable serosa, numerous polypoid and papillary excrescences are noted on the serosal surface. Cross-sectioning demonstrates partially solid and cystic areas of light tan, focally hemorrhagic and necrotic tumor. One fragment shows a segment of fallopian tube that includes the fimbriated end, measuring 4.5 cm. in length and up to 0.5 cm. in diameter. The serosa of the fallopian tube appears smooth and uninvolved by tumor. However, the attached tissue that may represent a partially cystic ovary that has been previously opened is present, again showing numerous papillary excrescences on the surface, and measures 5.0 x 2.0 x 1.5 cm. The cut section of what may represent the ovary shows numerous papillary growths both within and outside of the ovary. Blocks submitted: A1 through A3 - right ovary and fallopian tube; A4 through A8 - representative remaining nodules. [REDACTED]

The fourth container is labelled "uterus and cervix" and consists of an 81 gram uterus that measures 8.5 x 5.0 x 4.0 cm. The uterine serosa is predominantly smooth with a few scattered, contracted, scar-like nodular areas noted on the anterior surface. The cervix measures 3.3 x 3.0 cm with a transverse os that measures 0.6 cm. The cervical mucosa is smooth and gray-pink with scattered petechiae. Attached to the uterus is a portion of the left adnexal soft tissue that measures 4.0 x 3.5 x 1.0 cm. A fallopian tube segment or ovary is not identified grossly. The uterus is bivalved to reveal a roughly triangular endometrial cavity that measures 3.5 x 1.5 cm lined by a focally hemorrhagic, flat endometrium that measures less than 0.1 cm in thickness. The endocervical canal is grossly unremarkable. Serial sectioning through the myometrium shows a uniformly trabeculated, pink-tan myometrium that measures 1.5 cm. in thickness. Blocks submitted: B1 - anterior cervix; B2 - posterior cervix; B3 and B4 - anterior and posterior endomyometrium; B5 - thickened uterine serosa; B6 - representative left adnexal tissue. Jar 2.

The fifth container is labelled "right external iliac lymph node"

[page 5 of 8]
[REDACTED]

Surg. Path. No.:

Name:

GROSS (continued)

and consists of multiple firm to rubbery fragments of nodular tissue admixed with adipose tissue measuring in aggregate, 9.5 x 6.0 x 3.0 cm. The individual nodules grossly appear to be lymph nodes replaced by tumor and range from 0.9 x 0.5 x 0.5 cm. up to groups of enlarged, matted lymph nodes that measure 5.0 x 4.0 x 3.0 cm. A representative section of each nodule submitted labelled C1 through C7 (C6 and C7 represent a section of one lymph node).

The sixth container is labelled "para-aortic lymph node" and consists of multiple irregular, nodular fragments of pink-tan tissue measuring in aggregate, 5.5 x 5.0 x 3.0 cm. The largest fragment appears to represent multiple matted nodules and measures 5.0 x 3.0 x 2.5 cm. Sectioning demonstrates numerous matted nodules that are grossly replaced by tumor. Blocks submitted: D1 and D2 - largest nodule; D3 - representative section of smaller nodule.

The seventh container is labelled "left external iliac lymph node" and consists of multiple soft, irregular fragments of yellow-tan fibrofatty tissue measuring 5.0 x 3.0 x 1.0 cm. in aggregate. Multiple light tan nodules are dissected from the adipose tissue, ranging from 0.3 cm. in greatest dimension up to 2.5 x 1.0 x 0.3 cm.

The eighth container is labelled "omentum" and consists of a flat, irregular sheet of soft, yellow omental adipose tissue that measures 35 x 11 x 1 cm. A focal firm area is palpable, and sectioning in this region demonstrates a tan-yellow nodule that measures 1.5 cm. in greatest dimension. Sectioning through the remainder of the omentum shows no grossly visible nodules. The palpable nodule is labelled F1 and representative remaining tissue is labelled F2 and F3.

COMMENT

Both the right and left ovaries are replaced by a poorly differentiated papillary serous adenocarcinoma. The tumor shows a predominant papillary and cribriform architecture but also shows significant areas of solid proliferation. Cystic areas lined by flattened layers of tumor cells are also present. The tumor cells are large with marked cellular and nuclear pleomorphism, and moderate amounts of granular eosinophilic cytoplasm. Mitotic figures are numerous and foci of necrosis are easily identified. Focal areas also show clear cell differentiation.

[page 6 of 8]
Surg. Path. No.:

Name:

COMMENT (continued)

The tumor grossly and microscopically involved the surfaces of the ovaries, the mesovarium, and microscopically also involved the left fallopian tube. The thickened areas on the uterine serosa noted grossly represented foci of metastatic tumor. Many of the regional lymph nodes were replaced by tumor, and some of the nodules showed no identifiable residual lymph node tissue, and may represent soft tissue metastases.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1a. A neoplasm is PRESENT.

2. The HISTOLOGIC DIAGNOSIS is: Serous adenocarcinoma

3. The LOCATIONS OF THE PRIMARY TUMORS are:

Right and left ovary (synchronous primary tumors)

4. The FIGO GRADE of the tumor is:

II (Tumor composed of 5-50% solid cellular nests)

5. The NUCLEAR (BRODERS') GRADE of the tumor is:

G3 (Poorly-differentiated)

6. Tumor IS identified on the ovarian surfaces.

7. Tumor DOES invade the mesovarium.

8. Tumor DOES invade the adjacent fallopian tube.

9. Tumor invasion of the pelvic soft tissue CANNOT BE EVALUATED.

10. Tumor involvement of the pelvic peritoneum IS PRESENT.

11. Metastatic involvement of the EXTRAPELVIC peritoneum is PRESENT.

12. Metastatic involvement of the omentum is PRESENT.

13. The maximum dimension of tumor implants outside the true pelvis is 1.0 cm.

14. Metastatic involvement of the uterine serosa is PRESENT.

15. Metastatic involvement of the endometrium is ABSENT.

16. Regional lymph node metastases are PRESENT.

Extracapsular extension of tumor is PRESENT.

17. The total number of regional lymph nodes examined is 27.

18. The total number of metastatically-involved regional lymph nodes is 18.

19. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM SCHEME
T3c

FIGO SCHEME
IIIC

DEFINITION
Macroscopic peritoneal
metastasis beyond true pelvis
measuring greater than 2 cm in
greatest dimension, OR
Regional lymph node metastasis
OR Metastasis to capsule of

[page 7 of 8]
[REDACTED]

Name:

Surg. Path. No.:

[REDACTED]

COMMENT (continued)

liver.

THE REGIONAL LYMPH NODES are classified as:

N1 (Nodes contain metastatic tumor)

THE STATUS OF DISTANT TUMOR SITES is classified as:

MX (Status cannot be assessed)

20. The FINAL AJCC/FIGO STAGE IS AT LEAST:

AJCC SCHEME

FIGO SCHEME

3c

(T3c/ N0/ M0) OR

IIIC

(Any T/ N1/ M0)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

{End of Report}

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file fdb149d3-4f0d-4544-af69-845bbfd862a9 (TCGA-24-2027.8A4D0373-9D57-4CF7-AC78-D8B558D43DF6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).